Somatic mutation profile of tumor specimen TCGA-CV-A465-01A (aliquot TCGA-CV-A465-01A-11D-A25Y-08) from TCGA case TCGA-CV-A465, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 24.7 years (9,015 days).
Specimen TCGA-CV-A465-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad4f7743-13a9-40a2-b325-b53356f82c1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A465-10A (Blood Derived Normal), aliquot TCGA-CV-A465-10A-01D-A25Y-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b019b461-5aeb-4c5a-a5d2-dfdcf7bf2131

The open-access MAF lists 40 somatic variants for this specimen: 32 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 26, Silent 8, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- POLG | c.3412C>T p.R1138C | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767138032, CM083032, COSV99174962; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 28/81 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ZEB2 | c.1027C>T p.R343* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as rs786204815, CM031406, COSV100356564; ClinVar: pathogenic; called by muse, mutect2, varscan2
- C1QBP | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1332677858, COSV99852243; called by muse, mutect2, varscan2
- CDKN2A | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as rs587782797, CM1414339, COSV58697439, COSV58704986; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CMTM2 | c.115C>G p.Q39E | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.092); catalogued as COSV99216547; called by muse, mutect2
- CRY2 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769770457, COSV101314596, COSV101314610; called by muse, mutect2, varscan2
- DTX1 | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV99921997, COSV99922046; called by muse, mutect2
- DYNC1H1 | c.5312G>T p.G1771V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100795181; called by muse, mutect2, varscan2
- E2F7 | c.1892C>T p.S631L | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as COSV100523747; called by muse, mutect2
- H3C13 | c.373A>G p.I125V | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); catalogued as COSV100516148; called by muse, mutect2, varscan2
- HAO1 | c.52G>C p.V18L | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV101113277; called by muse, mutect2, varscan2
- ITGA8 | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100959543; called by muse, mutect2, varscan2
- JCAD | c.2195C>T p.T732M | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV64759450; called by muse, mutect2, varscan2
- KATNIP | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs150389178; called by muse, mutect2
- KRT14 | c.901G>C p.D301H | Missense Mutation (SNP) | VAF 43/299 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99391115; called by muse, mutect2, varscan2
- NEGR1 | c.695C>G p.S232C | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100165076; called by muse, mutect2, varscan2
- NRAP | c.3613C>T p.R1205W (on ENST00000359988 / NM_001322945.2; = p.R1170W on NM_006175.4) | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377301664; called by muse, mutect2, varscan2
- ORC2 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.343); catalogued as COSV52237059; called by muse, mutect2, varscan2
- PARP10 | c.2341G>T p.A781S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100478206; called by muse, mutect2, varscan2
- PAXBP1 | c.1026C>A p.Y342* | Nonsense Mutation (SNP) | VAF 11/108 reads (10%) | catalogued as COSV99269440; called by muse, mutect2
- SLC12A2 | c.3630C>G p.F1210L | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV99321402; called by muse, varscan2
- SLC5A5 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99715262; called by muse, mutect2, varscan2
- SOGA1 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs541773189, COSV52915340; called by muse, mutect2
- SS18L1 | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.261); catalogued as rs761829812, COSV59209177, COSV59212441; called by muse, mutect2, varscan2
- TAPBPL | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV56948978; called by muse, mutect2
- TMEM132B | c.2039G>T p.R680M | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100170480, COSV54772824; called by muse, mutect2, varscan2
- UPF3B | c.925C>T p.L309F (on ENST00000276201 / NM_080632.3; = p.L296F on NM_023010.3) | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.922); catalogued as COSV99352307; called by muse, mutect2, varscan2
- F2RL2 | c.156del p.S54Lfs*13 | Frame Shift Del (DEL) | VAF 15/146 reads (10%) | called by mutect2, pindel, varscan2
- HUWE1 | c.1046_1047del p.C349Yfs*23 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | called by mutect2, pindel
- KRT5 | c.920_927+15del p.X307_splice | Splice Site (DEL) | VAF 9/99 reads (9%) | called by pindel, varscan2*
- NOTCH1 | c.3931del p.C1311Afs*134 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- ADAMTS17 | c.663G>A p.E221= | Silent (SNP) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- ADGRV1 | c.4473G>A p.T1491= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as rs774213074, COSV101316276; called by muse, mutect2, varscan2
- GFOD1 | c.1134C>T p.S378= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs1204317779, COSV101015176; called by muse, mutect2, varscan2
- KMT2C | c.3642G>A p.V1214= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV100074846; called by muse, mutect2, varscan2
- OR5B12 | c.576C>T p.I192= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV100222514; called by muse, mutect2, varscan2
- PCDHGA4 | c.102G>A p.A34= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs1305434315, COSV99543311; called by muse, mutect2, varscan2
- PHF8 | c.1842G>A p.T614= (on ENST00000357988 / NM_001184896.1; = p.T578= on NM_015107.3) | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs369182537, COSV57683918; called by muse, mutect2, varscan2
- TJAP1 | c.159C>G p.R53= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV99447197; called by muse, mutect2, varscan2
